Somatic mutation profile of tumor specimen TCGA-37-4129-01A (aliquot TCGA-37-4129-01A-01D-1352-08) from TCGA case TCGA-37-4129, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 52.4 years (19,154 days).
Specimen TCGA-37-4129-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7cff49f-16e2-469c-a185-bf1dacfd6649.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-37-4129-10A (Blood Derived Normal), aliquot TCGA-37-4129-10A-01D-1352-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b67c7b90-14c3-485d-b9c8-befbbdec4448

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHAD | c.673A>G p.K225E | Missense Mutation (SNP) | VAF 31/336 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV99366273; called by muse, mutect2
- ZDHHC23 | c.73T>G p.C25G | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100362229; called by muse, mutect2, varscan2
- LRRC75A | c.321del p.I108Sfs*33 (on ENST00000470794 / NM_001113567.3; = p.I108Sfs*199 on NM_207387.4) | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel
- CORO6 | c.303A>G p.S101= | Silent (SNP) | VAF 29/270 reads (11%) | catalogued as COSV100801397; called by muse, mutect2, varscan2
- MAK | c.586T>C p.L196= | Silent (SNP) | VAF 10/309 reads (3%) | catalogued as COSV100504573; called by muse, mutect2
- RNF186 | c.189C>T p.C63= | Silent (SNP) | VAF 16/177 reads (9%) | catalogued as rs200709475, COSV100909111; called by muse, mutect2
- TOGARAM2 | c.2109C>A p.V703= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV101091353; called by muse, mutect2
